Somatic mutation profile of tumor specimen TCGA-OR-A5LL-01A (aliquot TCGA-OR-A5LL-01A-11D-A29I-10) from TCGA case TCGA-OR-A5LL, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 75.6 years (27,607 days).
Specimen TCGA-OR-A5LL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 788989dd-3d84-4da0-9f54-ef973a423715.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-OR-A5LL-10A (Blood Derived Normal), aliquot TCGA-OR-A5LL-10A-01D-A29L-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8f8bd07d-95a7-4bac-80e0-4c8e8a8e50e5

The open-access MAF lists 49 somatic variants for this specimen: 37 protein-altering or splice-affecting, 11 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 11, Frame Shift Ins 2, Intron 1, Frame Shift Del 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BPIFB4 | c.356G>A p.R119Q | Missense Mutation (SNP) | VAF 8/121 reads (7%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs373461211; called by muse, mutect2
- FAM124B | c.250C>T p.R84C | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); catalogued as rs1280865122, COSV54739336; called by muse, mutect2, varscan2
- FAM161B | c.860A>T p.H287L (on ENST00000651776; = p.H224L on NM_152445.3) | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs759141048, COSV54103153; called by muse, mutect2, varscan2
- FMO1 | c.1421G>A p.R474H | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs28360433; called by muse, mutect2, varscan2
- FRAS1 | c.4267C>T p.H1423Y | Missense Mutation (SNP) | VAF 39/118 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.869); catalogued as rs1346192103; called by muse, mutect2, varscan2
- MBD6 | c.2843A>C p.K948T | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.969); catalogued as COSV63074263; called by muse, mutect2
- MMP19 | c.899C>T p.P300L | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.102); catalogued as rs758007752; called by muse, mutect2, varscan2
- NLRP1 | c.3860G>A p.G1287D | Missense Mutation (SNP) | VAF 19/22 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1407715631, COSV52557740; called by muse, mutect2, varscan2
- PCDHGB2 | c.1676C>T p.A559V | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.604); catalogued as COSV54017424; called by muse, mutect2, varscan2
- RGS22 | c.2533C>T p.P845S | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.503); catalogued as COSV62662011; called by muse, mutect2, varscan2
- SHROOM4 | c.1729C>T p.R577C | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1557255145, COSV99173004; called by muse, mutect2, varscan2
- TFAP2C | c.202G>A p.A68T | Missense Mutation (SNP) | VAF 4/68 reads (6%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV52371193; called by muse, mutect2
- AKAP4 | c.2312A>G p.Q771R | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.562); called by muse, mutect2, varscan2
- CD300A | c.502C>A p.Q168K | Missense Mutation (SNP) | VAF 23/125 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- CDKN2AIPNL | c.253C>G p.L85V | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT tolerated (0.75); PolyPhen possibly damaging (0.72); called by muse, mutect2
- CLK1 | c.1206G>A p.M402I | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- COL4A6 | c.428G>T p.G143V | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CP | c.2850G>C p.E950D | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DNAJC14 | c.2024C>T p.A675V | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- DOCK5 | c.2638_2646del p.P880_L882del | In Frame Del (DEL) | VAF 8/24 reads (33%) | called by pindel, varscan2*
- DZIP3 | c.3298A>G p.N1100D | Missense Mutation (SNP) | VAF 89/169 reads (53%) | SIFT tolerated (0.69); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ERCC5 | c.8T>A p.V3D | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GPR50 | c.1232C>G p.S411C | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.431); called by muse, mutect2, varscan2
- LONP1 | c.1015A>C p.T339P | Missense Mutation (SNP) | VAF 22/143 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- LOX | c.1241T>G p.I414S | Missense Mutation (SNP) | VAF 16/246 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2
- NLRP3 | c.995G>A p.S332N | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OLIG2 | c.289G>A p.D97N | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.626); called by muse, mutect2, varscan2
- OR10J1 | c.433G>T p.V145F | Missense Mutation (SNP) | VAF 78/757 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- OR2B6 | c.578C>T p.T193I | Missense Mutation (SNP) | VAF 52/120 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- PM20D1 | c.1472C>G p.T491R | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.49); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PRAMEF4 | c.1391G>C p.G464A | Missense Mutation (SNP) | VAF 28/196 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); called by muse, varscan2
- RABL2B | c.343dup p.W115Lfs*20 | Frame Shift Ins (INS) | VAF 24/98 reads (24%) | called by mutect2, pindel, varscan2
- RFC1 | c.1613dup p.L538Ffs*24 | Frame Shift Ins (INS) | VAF 8/74 reads (11%) | called by mutect2, pindel, varscan2
- SLIT1 | c.2203C>T p.P735S | Missense Mutation (SNP) | VAF 37/184 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLITRK3 | c.65C>T p.T22I | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- WNT2 | c.603_604del p.L202Efs*55 | Frame Shift Del (DEL) | VAF 9/26 reads (35%) | called by mutect2, pindel*, varscan2*
- ZRANB3 | c.2672C>T p.T891I | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT tolerated (0.28); PolyPhen benign (0.001); called by muse, varscan2
- ADAM21 | c.1792A>C p.R598= | Silent (SNP) | VAF 137/294 reads (47%) | called by muse, mutect2, varscan2
- CSMD2 | c.1242C>T p.G414= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as COSV99596970; called by muse, mutect2, varscan2
- DCTN1 | c.3744G>A p.V1248= | Silent (SNP) | VAF 6/31 reads (19%) | called by muse, mutect2, varscan2
- KLHL3 | c.21G>A p.K7= | Silent (SNP) | VAF 12/82 reads (15%) | called by muse, mutect2, varscan2
- KLHL30 | c.1557C>T p.G519= | Silent (SNP) | VAF 18/138 reads (13%) | catalogued as rs1193070255, COSV100014045, COSV59975838; called by muse, varscan2
- LRP10 | c.1206C>T p.G402= | Silent (SNP) | VAF 8/64 reads (13%) | catalogued as rs777781406; called by muse, mutect2, varscan2
- PCDHGB1 | c.1953C>T p.S651= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as rs772410475, COSV53962464; called by muse, mutect2, varscan2
- PML | c.1776C>T p.T592= | Silent (SNP) | VAF 9/69 reads (13%) | called by muse, mutect2, varscan2
- PSAT1 | c.327T>G p.A109= | Silent (SNP) | VAF 7/81 reads (9%) | catalogued as COSV100716518; called by muse, mutect2
- RIC1 | c.1686A>G p.Q562= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as rs1476388415; called by muse, mutect2
- UPF1 | c.1713C>G p.A571= (on ENST00000599848 / NM_001297549.2; = p.A560= on NM_002911.4) | Silent (SNP) | VAF 21/109 reads (19%) | called by muse, mutect2, varscan2
- GRIK2 | c.2563-4351C>A | Intron (SNP) | VAF 37/154 reads (24%) | catalogued as COSV59753297; called by muse, mutect2, varscan2
